FM case AD13889 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/b1eb1789-5f32-4ce1-9eca-b47a3762e45c

Female, 52.8 years: Metaplastic carcinoma, NOS (ICD-O-3 8575/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
